Gene-level copy-number profile of tumor specimen TARGET-40-PAVDTY-01A from TARGET case TARGET-40-PAVDTY, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.4 years (4,898 days).
Specimen TARGET-40-PAVDTY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.8eba4e96-0080-5b6e-b0ad-47395e6e3f0a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAVDTY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 406 have no estimate.
https://portal.gdc.cancer.gov/files/df192bdf-04a8-4f96-85f1-822890e34e4c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 106; copy number 1: 3,943; copy number 2: 15,377; copy number 3: 25,615; copy number 4: 11,195; copy number 5: 1,613; copy number 6: 713; copy number 7: 115; copy number 8: 226; copy number 9: 251; copy number 10: 21; copy number 11: 94; copy number 12: 50; copy number 13: 184; copy number 14: 188; copy number 15: 101; copy number 16: 6; copy number 17: 251; copy number 19: 85; copy number 20: 49; copy number 21: 34.

Homozygous deletions (total copy number 0; autosomes only): 106 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:29,054,570–29,290,726, 2 genes (within-gene range 0–2): RBMS3-AS3, MESTP4.
- chr3:116,709,235–116,965,227, 6 genes: TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P.
- chr8:39,314,591–39,522,852, 2 genes (within-gene range 0–3): ADAM5, ADAM3A.
- chr9:15,464,066–16,870,843, 12 genes (within-gene range 0–2): PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1.
- chr9:20,341,669–25,089,151, 84 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,655 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:70,852,353–98,272,658, 411 genes, copy number 8–21 (within-gene range 5–21) (broad region; genes not listed).
- chr1:100,586,649–105,893,517, 51 genes, copy number 7: AC099670.1, LINC01349, AC099670.3, AC099670.2, VCAM1, EXTL2, AC104506.1, SLC30A7, HNRNPA1P68, DPH5, AC093157.2, AC093157.1, AC093157.3, AC119501.1, AL109741.1, S1PR1, AL109741.2, PPIAP7, LINC01307, LINC01709, RNU6-965P, RPSAP19, OLFM3, RNU6-352P, AL356280.1, DNAJA1P5, AC114485.1, AC099567.1, COL11A1, SOD2P1, AC095032.2, AC095032.1, RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1, AMY1C, AL136455.1, AC092506.1, FTLP17, AL591888.1, CDK4P1, LINC01676, SEPTIN2P1, AL512844.2, AL512844.1.
- chr2:76,747,719–77,593,319, 1 gene, copy number 11 (within-gene range 4–11): LRRTM4.
- chr2:76,985,965–78,931,146, 13 genes, copy number 7–11: LRRTM4-AS1, AC013716.1, AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P.
- chr4:42,892,396–43,598,844, 9 genes, copy number 7: RN7SKP82, GRXCR1, AC111198.1, AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P.
- chr4:52,872,982–53,366,066, 1 gene, copy number 9 (within-gene range 5–9): SCFD2.
- chr4:53,265,461–58,118,070, 101 genes, copy number 8–9 (broad region; genes not listed).
- chr6:35,258,909–58,438,364, 475 genes, copy number 8–20 (within-gene range 3–20) (broad region; genes not listed).
- chr12:7,812,512–7,972,759, 10 genes, copy number 9 (within-gene range 5–9): SLC2A14, AC006517.2, Y_RNA, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6.
- chr12:37,575,587–40,106,089, 30 genes, copy number 8 (within-gene range 3–8): ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13.
- chr15:66,984,103–67,065,268, 1 gene, copy number 7 (within-gene range 4–7): AC087482.1.
- chr17:7,705,202–8,745,219, 59 genes, copy number 8–12: EFNB3, DNAH2, RPL29P2, KDM6B, TMEM88, NAA38, CYB5D1, AC104581.4, CHD3, SCARNA21, RNF227, KCNAB3, AC104581.2, TRAPPC1, CNTROB, AC104581.1, GUCY2D, AC104581.3, ALOX15B, AC129492.2, ALOXE3P1, ALOX12B, AC129492.1, MIR4314, ALOXE3, HES7, PER1, MIR6883, AC129492.3, VAMP2, TMEM107, SNORD118, AC129492.4, MIR4521, AC129492.5, AURKB, LINC00324, CTC1, PFAS, AC135178.6, SLC25A35, RANGRF, AC135178.7, ARHGEF15, AC135178.2, AC135178.1, AC135178.5, ODF4, KRBA2, AC135178.4, AC135178.3, RPL26, RNF222, NDEL1, MYH10, RNU7-43P, PPIAP52, AC025518.1, CCDC42.
- chr17:10,258,762–10,880,895, 30 genes, copy number 8: RPS27AP1, AC005291.2, MYH13, AC005291.1, AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1, MYH3, AC002347.1, SCO1, AC002347.2, ADPRM, TMEM220, MAGOH2P, TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21.
- chr17:11,953,889–22,706,703, 436 genes, copy number 7–16 (within-gene range 5–16) (broad region; genes not listed).
- chr18:65,105,873–68,114,878, 25 genes, copy number 7: AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19, RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1.
- chr18:68,258,080–68,278,243, 2 genes, copy number 7: LINC01912, AC022968.1.

Autosomal genes at a single copy (total copy number 1): 1,556. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
